Surgical pathology report (de-identified scan), TCGA case TCGA-D8-A1JA, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D8-A1JA-01A (Primary Tumor).

1ED-0-3

Carcinoma, infiltrating; ductal, nos 8500/3

Site: breast, nos C50.9

page 1 / 1

3/1/11

ew

Department of Cancer Pathology

copy No. :

Date: (

Examination: Histopathological examination

Internal invoice No.

Cost of diagnostic procedure

Examination No.:

Patient: XXX

PESEL: XXX

Age:

Gender: F

Material: Multiple organ resection – left breast with axillary tissues

Unit in charge:

Physician in charge:

Material collected on:

Material received on: :

Expected time of examination: up to 8 working days

Clinical diagnosis: Cancer of the left breast. Toilet mastectomy.

Examination performed on: (

Histopathological diagnosis:

Invasive ductal carcinoma of the left breast.

Results of immunohistochemical examination:

Estrogen receptors found in less than 10% of neoplastic cell nuclei.

No progesterone receptors found in neoplastic cell nuclei.

HER2 protein stained with HercepTest™ by DAKO.

Positive reaction in invasive cancerous cells (Score = 3+)

Compliance validated by:

Dis/VSynchronous Primary Noted		
Cash/In/Out/Ref		

Source: NCI Genomic Data Commons file 17aa7df6-632a-4895-af9f-cfed1a921a70 (TCGA-D8-A1JA.51A2B7B5-0CDD-427D-BC82-5498810B2641.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).